Somatic mutation profile of tumor specimen TCGA-B5-A1MU-01A (aliquot TCGA-B5-A1MU-01A-11D-A13L-09) from TCGA case TCGA-B5-A1MU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 79.5 years (29,027 days).
Specimen TCGA-B5-A1MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0da339d9-6015-4883-833b-90e849b8e2f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MU-10A (Blood Derived Normal), aliquot TCGA-B5-A1MU-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a10b8ce-910c-4083-8f08-92100d6eba31

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 51/92 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1510-1G>T p.X504_splice | Splice Site (SNP) | VAF 10/93 reads (11%) | catalogued as COSV61658202; called by muse, mutect2, varscan2
- APLP1 | c.577A>G p.M193V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55703931; called by muse, mutect2, varscan2
- BMERB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV55508962; called by muse, mutect2, varscan2
- CDK5RAP1 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV59427197; called by muse, mutect2
- CEL | c.968C>T p.P323L (on ENST00000673714; = p.P320L on NM_001807.6) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546216566, COSV60827952; called by muse, mutect2, varscan2
- COL4A5 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372369187, COSV60363379; called by muse, mutect2, varscan2
- CRNKL1 | c.293C>G p.P98R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs750771442, COSV55632760; called by muse, mutect2, varscan2
- ESCO2 | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1489877013, COSV59414930, COSV59415834; called by muse, mutect2, varscan2
- KIF4B | c.3484G>T p.A1162S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as COSV70529924; called by muse, mutect2, varscan2
- MYH1 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV56847025, COSV56850042; called by muse, mutect2, varscan2
- NUP98 | c.4537C>T p.R1513* (on ENST00000359171 / NM_001365126.1; = p.R1496* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV61433047; called by muse, mutect2
- NVL | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs200984793, COSV55873078; called by muse, mutect2, varscan2
- OR8J1 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57318672; called by muse, mutect2, varscan2
- PA2G4 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57569017; called by muse, mutect2, varscan2
- PIBF1 | c.1381A>T p.K461* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV58324139; called by muse, mutect2, varscan2
- PRDM15 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs149203937; called by muse, mutect2, varscan2
- PTPRD | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs775957349, COSV61954458, COSV61980019; called by mutect2, varscan2
- PTPRT | c.3817G>A p.V1273M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61987836; called by muse, mutect2, varscan2
- RLIM | c.1415G>T p.S472I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV60327105; called by muse, mutect2
- SCUBE3 | c.1216A>C p.S406R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as COSV51457498; called by muse, mutect2, varscan2
- SMG1 | c.9639A>T p.Q3213H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV67171999; called by muse, mutect2
- ZNF362 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as COSV65031505; called by muse, mutect2
- ZSCAN4 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1370021057, COSV59000204; called by muse, mutect2, varscan2
- AP1G1 | c.2076A>G p.S692= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV55490313; called by muse, mutect2, varscan2
- H2AC17 | c.306C>T p.T102= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV58152844, COSV58152851; called by muse, mutect2
- PANX1 | c.978C>T p.N326= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV57134107; called by muse, mutect2, varscan2
- SUV39H1 | c.771C>T p.G257= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV61920884; called by muse, mutect2
- C3P1 | n.3076C>T | RNA (SNP) | VAF 10/68 reads (15%) | catalogued as rs541621901; called by muse, mutect2
